Somatic mutation profile of tumor specimen TCGA-DM-A282-01A (aliquot TCGA-DM-A282-01A-12D-A16V-10) from TCGA case TCGA-DM-A282, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Hepatic flexure of colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.0 years (22,265 days).
Specimen TCGA-DM-A282-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff7bef70-9f4a-4d3d-8029-ae4e31344fdb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A282-10A (Blood Derived Normal), aliquot TCGA-DM-A282-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e06daf9-d696-4c1e-910b-ccf39949d689

The open-access MAF lists 104 somatic variants for this specimen: 77 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 25, Frame Shift Del 3, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 1, Splice Region 1, RNA 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4099C>T p.Q1367* | Nonsense Mutation (SNP) | VAF 18/48 reads (38%) | hotspot (GDC flag); catalogued as rs121913328, CM940072, COSV57323776, COSV57337799; ClinVar: likely pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 37/111 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.465dup p.T156Yfs*6 | Frame Shift Ins (INS) | VAF 27/88 reads (31%) | catalogued as rs1180724229; called by mutect2, varscan2
- ANKS1A | c.953C>A p.T318N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV64461548; called by muse, mutect2, varscan2
- APP | c.901C>G p.R301G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100696374, COSV60999859, COSV61002219; called by mutect2, varscan2
- ASAP3 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs370249845, COSV60875447; called by muse, mutect2, varscan2
- ATP8B2 | c.2699G>A p.R900Q (on ENST00000672630; = p.R867Q on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59246507, COSV59247372; called by muse, mutect2, varscan2
- BAP1 | c.2152C>T p.R718W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs1186981831, COSV56231033, COSV56237466; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2584G>A p.D862N | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV63245385; called by muse, mutect2, varscan2
- BTBD11 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99775183; called by muse, mutect2, varscan2
- CARMIL3 | c.2200A>T p.S734C | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57726890; called by muse, mutect2, varscan2
- CEP85L | c.1786C>T p.R596C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs577126537, COSV63821192; called by muse, mutect2, varscan2
- CLEC1A | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.208); catalogued as rs147882348, COSV100191187, COSV59531017; called by muse, mutect2, varscan2
- COL6A6 | c.4399G>A p.G1467R | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546403459, COSV62022838, COSV62026110; called by muse, mutect2, varscan2
- CTNNA2 | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58157532; called by muse, mutect2, varscan2
- CYP4A22 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs780190981, COSV53737797; called by muse, mutect2, varscan2
- DAB1 | c.885+1G>A p.X295_splice (on ENST00000371231; = p.X262_splice on NM_021080.5 and 5 other RefSeq transcripts) | Splice Site (SNP) | VAF 20/64 reads (31%) | catalogued as rs201318657, COSV64693836; called by muse, mutect2, varscan2
- DNTT | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs1564871244, COSV64523130; called by muse, mutect2, varscan2
- DSG4 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57392984; called by muse, mutect2, varscan2
- ELFN2 | c.746C>T p.S249L | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.66); PolyPhen benign (0.037); catalogued as rs377398519; called by muse, mutect2, varscan2
- FBXL7 | c.1027C>T p.R343W | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs375745885; called by muse, varscan2
- FLG | c.6611G>A p.R2204K | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.609); catalogued as rs867126193, COSV100911303; called by muse, mutect2, varscan2
- FRMPD4 | c.3805C>A p.P1269T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.091); catalogued as COSV101042491; called by muse, mutect2, varscan2
- GLS2 | c.1727A>T p.Q576L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as COSV57665636; called by muse, mutect2, varscan2
- GPCPD1 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754108015, COSV66831048; called by muse, mutect2, varscan2
- GRIK1 | c.2822G>A p.R941Q (on ENST00000327783 / NM_001330994.2; = p.R897Q on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs748380852, COSV100583163; called by muse, mutect2, varscan2
- GRK6 | c.1694G>A p.C565Y (on ENST00000355472 / NM_001004106.3; = p.A566T on NM_002082.3) | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.205); catalogued as COSV62682944; called by muse, mutect2
- IGDCC4 | c.2702C>T p.T901M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs200877185; called by muse, mutect2, varscan2
- IL31RA | c.1906G>T p.V636L | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61694893; called by muse, mutect2, varscan2
- JAG2 | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59310056; called by muse, mutect2, varscan2
- KCNF1 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs1326257301, COSV54462906; called by muse, mutect2
- KIAA1210 | c.1521G>A p.M507I | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68177710; called by muse, mutect2, varscan2
- LAMA4 | c.4493G>A p.R1498H (on ENST00000230538 / NM_001105206.3; = p.R1491H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as rs147556641; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGI2 | c.3154G>A p.A1052T | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs781523898, COSV100833815; called by muse, mutect2, varscan2
- MCC | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs199564726; called by muse, mutect2, varscan2
- MICALL2 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.459); catalogued as COSV99875784; called by muse, mutect2, varscan2
- MRPS22 | c.1061G>A p.R354H (on ENST00000310776 / NM_001363893.1; = p.R355H on NM_020191.4) | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs755925113, COSV60349364; called by muse, mutect2, varscan2
- MS4A3 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs775321420, COSV53936568; called by muse, mutect2, varscan2
- MTARC2 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.216); catalogued as COSV63765784; called by muse, mutect2, varscan2
- MYO1F | c.2527C>A p.L843M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV57796221; called by muse, mutect2, varscan2
- NOXRED1 | c.843C>G p.C281W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV53628252; called by muse, mutect2, varscan2
- NRG1 | c.1109T>C p.V370A (on ENST00000405005 / NM_013964.5; = p.V375A on NM_013956.5) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs1327566586, COSV55163244; called by muse, mutect2, varscan2
- NTM | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs750771964, COSV100867963; called by mutect2, varscan2
- OR7D4 | c.731A>G p.H244R | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100432651; called by muse, mutect2, varscan2
- PANX2 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1160790229, COSV50299490; called by muse, mutect2, varscan2
- PCDH17 | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs143494894; called by muse, mutect2, varscan2
- PCDHB1 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1416593174, COSV60631514; called by muse, mutect2, varscan2
- PCDHGA12 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs773372764, COSV52754977, COSV99337394; called by muse, mutect2, varscan2
- POLQ | c.6546C>T p.D2182= | Splice Region (SNP) | VAF 8/36 reads (22%) | catalogued as rs201717586, COSV51754015; called by muse, mutect2, varscan2
- PPP4R4 | c.2399A>C p.Y800S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.961); catalogued as COSV58555445; called by muse, mutect2, varscan2
- PRPS2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs1169475707, COSV66179665; called by muse, mutect2, varscan2
- ROBO1 | c.1948G>T p.D650Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71393379; called by muse, mutect2, varscan2
- RPH3A | c.700C>T p.R234C (on ENST00000389385 / NM_001143854.2; = p.R230C on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs145114678; called by muse, mutect2, varscan2
- RSPH9 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV64665073; called by muse, mutect2, varscan2
- RYR2 | c.14600T>A p.I4867N | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100768991; called by muse, mutect2, varscan2
- SFTPA1 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368889920; called by muse, mutect2, varscan2
- SLC13A3 | c.1478C>T p.P493L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746862161, COSV51717354; called by muse, mutect2, varscan2
- SLC39A10 | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62767962; called by muse, mutect2, varscan2
- SLITRK4 | c.1314G>C p.E438D | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.524); catalogued as COSV62024555, COSV62025705; called by muse, mutect2, varscan2
- SOS1 | c.2144A>G p.E715G | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.692); catalogued as COSV101216734; called by muse, mutect2, varscan2
- STAG1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV52612817; called by muse, mutect2, varscan2
- TAS2R30 | c.922C>T p.L308F | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.608); catalogued as rs761429313, COSV67857083; called by muse, mutect2, varscan2
- TCF7L2 | c.1094G>T p.R365I (on ENST00000355995 / NM_001367943.1; = p.R342I on NM_030756.5) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53342334; called by muse, mutect2, varscan2
- TEKT5 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.709); catalogued as rs747708531, COSV51589667; called by muse, mutect2, varscan2
- TMX2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as rs756199795, COSV53554815; called by muse, mutect2, varscan2
- TNXB | c.11230G>A p.A3744T (on ENST00000647633; = p.A3497T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs547169479, COSV64480792; called by muse, mutect2, varscan2
- WTAP | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 62/176 reads (35%) | catalogued as COSV61610095; called by muse, mutect2, varscan2
- XCR1 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183698296, COSV58569784; called by muse, mutect2, varscan2
- ZNF214 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV53481396; called by muse, mutect2, varscan2
- ZNF687 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs746046631, COSV100133950, COSV60678468; called by muse, varscan2
- ZNF691 | c.458C>T p.S153L (on ENST00000372502; = p.S122L on NM_015911.3) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs770548820, COSV100996069, COSV100996099; called by muse, mutect2, varscan2
- ZNF714 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as rs770862430, COSV52512583; called by muse, mutect2, varscan2
- BCL9 | c.1290del p.F430Lfs*21 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- KCNH5 | c.316del p.W106Gfs*9 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- MRPS7 | c.625_630del p.L209_L210del | In Frame Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- OR4A5 | c.391_398del p.L131Hfs*44 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- SAMD9L | c.63dup p.W22Mfs*4 | Frame Shift Ins (INS) | VAF 49/150 reads (33%) | called by mutect2, pindel, varscan2
- ADCY7 | c.2733C>A p.I911= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV54267683; called by muse, mutect2, varscan2
- CELSR1 | c.1068G>A p.S356= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs775705479, COSV53085638; called by muse, mutect2, varscan2
- CSMD1 | c.7512C>T p.N2504= (on ENST00000520002; = p.N2503= on NM_033225.6) | Silent (SNP) | VAF 30/59 reads (51%) | catalogued as rs560104234, COSV59348504; called by muse, mutect2, varscan2
- CSMD1 | c.5361C>T p.N1787= (on ENST00000520002; = p.N1786= on NM_033225.6) | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs34443453; called by muse, mutect2, varscan2
- CTRL | c.381C>T p.L127= | Silent (SNP) | VAF 61/168 reads (36%) | catalogued as rs1188452518, COSV52123826; called by muse, mutect2, varscan2
- EPHA10 | c.2052C>T p.S684= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs759686366, COSV57624633; called by muse, mutect2, varscan2
- EVC2 | c.3750C>T p.G1250= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs775355661, COSV60395501; called by muse, mutect2, varscan2
- GNB1L | c.21G>A p.P7= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs369925785; called by muse, mutect2, varscan2
- HPS1 | c.378C>T p.D126= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs765692546, COSV57268374, COSV57269344; called by muse, mutect2, varscan2
- KRT38 | c.396G>T p.L132= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as COSV55846328, COSV55846753; called by muse, mutect2, varscan2
- MSH6 | c.3477C>T p.Y1159= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as rs398123231, CD124191, CM117498, COSV52280667; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.41118C>A p.I13706= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV66693236; called by muse, mutect2, varscan2
- MYOM2 | c.2451C>T p.Y817= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs756033637, COSV100037100; called by muse, mutect2, varscan2
- NECAB3 | c.489G>A p.A163= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs767565816, COSV55776599; called by muse, mutect2, varscan2
- NPC1L1 | c.1575T>C p.C525= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99203794; called by muse, mutect2, varscan2
- PEBP4 | c.87G>A p.P29= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs369536370; called by muse, mutect2, varscan2
- PRKG1 | c.1920A>G p.E640= | Silent (SNP) | VAF 44/102 reads (43%) | catalogued as COSV64772207; called by muse, varscan2
- PTPRT | c.1947C>T p.P649= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as rs770357636, COSV100627373, COSV61989303; called by muse, mutect2, varscan2
- RYR2 | c.5658C>A p.G1886= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs745731983, COSV100768990; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLITRK1 | c.2079G>A p.S693= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV65674931; called by muse, mutect2, varscan2
- TBC1D13 | c.174A>G p.S58= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV99804349; called by muse, mutect2, varscan2
- UPF2 | c.1908A>C p.V636= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as COSV100707109; called by muse, mutect2
- ZNF175 | c.636C>T p.N212= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs143236411; called by muse, mutect2, varscan2
- ZNF354C | c.1452C>T p.T484= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs761541929, COSV59608621; called by muse, mutect2, varscan2
- ZNF415 | c.1512C>A p.S504= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as COSV99701396, COSV99701469; called by mutect2, varscan2
- DCHS2 | n.6356C>T | RNA (SNP) | VAF 38/74 reads (51%) | catalogued as rs765740474, COSV61773571; called by muse, mutect2, varscan2
- KRAS | c.*15_*17del | 3'UTR (DEL) | VAF 14/50 reads (28%) | called by pindel, varscan2
